Gene-level copy-number profile of tumor specimen TCGA-36-1581-01A from TCGA case TCGA-36-1581, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,272 days).
Specimen TCGA-36-1581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c59f2d68-22fb-496c-831a-17d42785f815.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1581-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0ab786a-08b6-4145-af57-04f454d932fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,042; copy number 2: 23,019; copy number 3: 21,407; copy number 4: 5,503; copy number 5: 3,739; copy number 6: 3,132; copy number 7: 644; copy number 8: 13; copy number 9: 62; copy number 12: 26; copy number 17: 31; copy number 21: 162; copy number 34: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1581-01): tumor purity 0.66, ploidy 2.93, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr8:31,497,423–31,598,204, 3 genes: AC068672.1, AC090816.1, RNA5SP261.
- chr8:33,859,480–35,093,509, 10 genes: AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene: AC090740.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,826 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,761,832–248,919,946, 2,786 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr2:79,025,686–79,185,523, 6 genes, copy number 6–12: REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1.
- chr2:79,269,905–79,649,359, 6 genes, copy number 12: AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264.
- chr2:153,871,922–157,380,414, 34 genes, copy number 6–12: GALNT13, PHBP4, AC009227.1, AC009227.2, RNA5SP107, AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1, LINC01876, HEBP2P1, AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP.
- chr2:174,501,952–180,007,297, 122 genes, copy number 5 (broad region; genes not listed).
- chr2:190,908,460–191,847,088, 17 genes, copy number 5 (within-gene range 2–5): STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2.
- chr2:191,881,182–191,882,205, 1 gene, copy number 5: DNAJB1P1.
- chr3:86,816,740–198,222,513, 1,835 genes, copy number 5 (broad region; genes not listed).
- chr5:271,670–438,291, 1 gene, copy number 9 (within-gene range 3–9): PDCD6-AHRR.
- chr5:321,759–44,828,592, 691 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr6:167,607–2,881,407, 47 genes, copy number 5 (within-gene range 4–5): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645.
- chr6:52,144,349–55,579,197, 79 genes, copy number 6 (broad region; genes not listed).
- chr6:55,939,790–57,646,850, 21 genes, copy number 6: NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1.
- chr8:32,440,704–33,600,023, 21 genes, copy number 5: NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:33,641,581–33,723,079, 3 genes, copy number 5: BUD31P1, RN7SL457P, VENTXP5.
- chr8:49,909,789–51,015,165, 6 genes, copy number 7 (within-gene range 4–7): SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1.
- chr10:44,712–42,997,681, 705 genes, copy number 5–7 (broad region; genes not listed).
- chr14:68,605,396–68,695,734, 5 genes, copy number 6: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1.
- chr14:73,958,010–106,875,071, 955 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:27,019,527–31,095,450, 230 genes, copy number 6 (broad region; genes not listed).
- chr17:31,133,182–31,138,518, 1 gene, copy number 6: AC079915.1.
- chr18:20,946,906–25,352,190, 98 genes, copy number 6 (broad region; genes not listed).
- chr18:48,475,487–54,959,461, 106 genes, copy number 5 (broad region; genes not listed).
- chr19:28,294,093–30,713,538, 50 genes, copy number 6–34 (within-gene range 2–34): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1.

Autosomal genes at a single copy (total copy number 1): 2,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
